Somatic mutation profile of tumor specimen 3324361b-df55-4e53-a2ef-4f8df2 (aliquot 3324361b-df55-4e53-a2ef-4f8df2_D6) from CPTAC case 11BR009, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 43.5 years (15,877 days).
Specimen 3324361b-df55-4e53-a2ef-4f8df2: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed293c7a-6bfc-48ca-806e-7d30b8cd41f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen af5441ab-b2ad-4a62-9973-6b3f9c (Blood Derived Normal), aliquot af5441ab-b2ad-4a62-9973-6b3f9c_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/931d2656-a14d-4d1b-a5d7-4c9bd81c74c0

The open-access MAF lists 125 somatic variants for this specimen: 94 protein-altering or splice-affecting, 20 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 20, Frame Shift Del 7, Nonsense Mutation 7, Intron 4, Splice Site 4, In Frame Del 3, 3'Flank 2, 5'Flank 2, 3'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.6559T>C p.F2187L | Missense Mutation (SNP) | VAF 101/334 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.024); catalogued as rs771549067, COSV52150068; called by muse, mutect2, varscan2
- ARHGAP19 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs559397638; called by muse, mutect2, varscan2
- CAMSAP1 | c.1022G>C p.R341T | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100409521; called by muse, mutect2, varscan2
- CAVIN1 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV63811378; called by mutect2, varscan2
- CEACAM6 | c.977C>A p.S326* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99555358, COSV99555564; called by muse, mutect2, varscan2
- CENPP | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 65/150 reads (43%) | catalogued as rs1308575636; called by muse, mutect2, varscan2
- CRB2 | c.1439C>A p.T480N | Missense Mutation (SNP) | VAF 134/449 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV63501802; called by muse, mutect2, varscan2
- DCST1 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 207/360 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.248); catalogued as rs1200793653, COSV99665427; called by muse, mutect2, varscan2
- DOCK5 | c.3041A>G p.N1014S | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV52409541; called by muse, mutect2, varscan2
- EIF2AK4 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs1409807052, COSV55468174; called by muse, mutect2, varscan2
- FA2H | c.117C>A p.F39L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as rs794729215, CM151648; called by muse, mutect2, varscan2
- GJB4 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs768318044; called by muse, mutect2, varscan2
- GLI1 | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV57359353; called by muse, mutect2, varscan2
- GOLPH3L | c.562C>A p.H188N | Missense Mutation (SNP) | VAF 127/452 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55045681; called by muse, mutect2, varscan2
- HBP1 | c.1362G>T p.Q454H | Missense Mutation (SNP) | VAF 112/310 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs768849170; called by muse, mutect2, varscan2
- INPP5A | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 86/133 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs1228547391; called by muse, mutect2, varscan2
- JMJD8 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs781370598; called by muse, mutect2, varscan2
- LRP2 | c.5003C>A p.A1668D | Missense Mutation (SNP) | VAF 126/232 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99789638; called by mutect2, varscan2
- LRRC43 | c.663-1G>T p.X221_splice | Splice Site (SNP) | VAF 50/157 reads (32%) | catalogued as COSV100336867; called by mutect2, varscan2
- MPO | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 162/598 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56569108; called by mutect2, varscan2
- MROH7 | c.1879G>T p.G627C | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.467); catalogued as COSV100273703; called by muse, mutect2, varscan2
- PKHD1 | c.3452C>T p.P1151L | Missense Mutation (SNP) | VAF 214/489 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs574099162, COSV61872779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PREX2 | c.4310C>A p.S1437* | Nonsense Mutation (SNP) | VAF 33/141 reads (23%) | catalogued as COSV55776384; called by muse, mutect2, varscan2
- PRL | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as rs764728645, COSV100123252, COSV60593577; called by muse, varscan2
- PSG11 | c.626A>T p.K209M | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60457744; called by mutect2, varscan2
- RHBDF2 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1287357466; called by muse, mutect2, varscan2
- RMDN2 | c.785A>G p.H262R (on ENST00000354545 / NM_001322212.2; = p.H440R on NM_144713.5) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs762730311; called by muse, mutect2, varscan2
- SEMA3G | c.2134C>T p.Q712* | Nonsense Mutation (SNP) | VAF 195/341 reads (57%) | catalogued as COSV51594534; called by muse, mutect2, varscan2
- SLC39A4 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 249/441 reads (56%) | SIFT tolerated (1); PolyPhen possibly damaging (0.499); catalogued as rs1554874127; called by muse, mutect2, varscan2
- TAAR8 | c.98T>G p.I33S | Missense Mutation (SNP) | VAF 118/196 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs753543784; called by muse, mutect2, varscan2
- USP31 | c.1780C>G p.Q594E | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs766064773; called by muse, mutect2, varscan2
- WT1 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 141/635 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV60067994; called by muse, mutect2, varscan2
- AHI1 | c.616A>G p.R206G | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, varscan2
- AKR1C1 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- AMIGO1 | c.1038G>T p.E346D | Missense Mutation (SNP) | VAF 142/366 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD13B | c.770T>C p.I257T | Missense Mutation (SNP) | VAF 84/241 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ATP1A3 | c.1846G>T p.V616F (on ENST00000545399 / NM_001256214.2; = p.V603F on NM_152296.5) | Missense Mutation (SNP) | VAF 122/379 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AXDND1 | c.903G>C p.Q301H | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BCL9 | c.2882_2892del p.M961Sfs*26 | Frame Shift Del (DEL) | VAF 24/156 reads (15%) | called by mutect2, pindel, varscan2
- CACNG7 | c.772T>G p.Y258D | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.369); called by mutect2, varscan2
- CAVIN1 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 87/211 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- CENPJ | c.3018_3029del p.R1007_L1010del | In Frame Del (DEL) | VAF 15/66 reads (23%) | called by mutect2, pindel, varscan2
- CHST11 | c.796del p.C266Afs*34 | Frame Shift Del (DEL) | VAF 132/360 reads (37%) | called by mutect2, pindel*, varscan2*
- COL15A1 | c.895_904del p.E299Wfs*6 | Frame Shift Del (DEL) | VAF 19/123 reads (15%) | called by mutect2, pindel, varscan2
- CUBN | c.5812G>A p.G1938R | Missense Mutation (SNP) | VAF 56/572 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.2); called by muse, mutect2
- DROSHA | c.1274A>T p.D425V | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DSTYK | c.2020G>C p.G674R | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- DTD1 | c.428T>A p.I143K | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- DZIP1 | c.556A>C p.T186P | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- EFCAB13 | c.2850_2864del p.K950_H954del | In Frame Del (DEL) | VAF 33/117 reads (28%) | called by mutect2, pindel, varscan2
- EGFLAM | c.1459C>G p.L487V | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- EPHA5 | c.722C>A p.A241D | Missense Mutation (SNP) | VAF 238/587 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXD4L3 | c.899_905del p.S300Tfs*26 | Frame Shift Del (DEL) | VAF 240/871 reads (28%) | called by pindel, varscan2
- GAP43 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GAPVD1 | c.1733G>A p.G578D | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GAS2L1 | c.427G>C p.V143L | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- GPR151 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by mutect2, varscan2
- KCNH2 | c.372G>A p.M124I | Missense Mutation (SNP) | VAF 154/475 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- LBP | c.516del p.D173Tfs*6 | Frame Shift Del (DEL) | VAF 10/99 reads (10%) | called by mutect2, pindel
- LILRB4 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MBTD1 | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 85/259 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MCMDC2 | c.1588G>T p.A530S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAA15 | c.2468T>A p.I823N | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- NACAD | c.4551G>C p.E1517D | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2
- NCKAP1 | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- NPR1 | c.1725G>T p.E575D | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR5W2 | c.188T>A p.L63H | Missense Mutation (SNP) | VAF 127/319 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PANK3 | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIAS3 | c.1287G>T p.Q429H | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PKP1 | c.1083C>G p.D361E | Missense Mutation (SNP) | VAF 161/634 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- PLCB2 | c.291G>C p.K97N | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- PLEKHG1 | c.1628T>C p.F543S | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLXNA3 | c.2533-1G>A p.X845_splice | Splice Site (SNP) | VAF 24/177 reads (14%) | called by muse, mutect2, varscan2
- PRKAR2B | c.985-1G>C p.X329_splice | Splice Site (SNP) | VAF 43/108 reads (40%) | called by muse, mutect2, varscan2
- RRAGC | c.47A>T p.Y16F | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUBCNL | c.141G>C p.M47I | Missense Mutation (SNP) | VAF 186/320 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by mutect2, varscan2
- SBF1 | c.712_756del p.F238_G252del | In Frame Del (DEL) | VAF 12/116 reads (10%) | called by mutect2, pindel
- SBF1 | c.579_604del p.Q194Lfs*49 | Frame Shift Del (DEL) | VAF 15/114 reads (13%) | called by mutect2, pindel, varscan2
- SENP5 | c.2065A>G p.R689G | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- SKIDA1 | c.2058A>T p.K686N | Missense Mutation (SNP) | VAF 78/235 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SLC25A19 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 36/178 reads (20%) | called by muse, mutect2, varscan2
- SMARCA2 | c.2364G>A p.W788* | Nonsense Mutation (SNP) | VAF 40/138 reads (29%) | called by muse, mutect2, varscan2
- SNX13 | c.620A>G p.E207G | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPINK5 | c.1650del p.V553Sfs*22 | Frame Shift Del (DEL) | VAF 156/413 reads (38%) | called by mutect2, pindel, varscan2
- STARD9 | c.8591T>A p.V2864D | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); called by mutect2, varscan2
- STOM | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.024); called by muse, mutect2
- TECTA | c.4889C>G p.T1630R | Missense Mutation (SNP) | VAF 207/336 reads (62%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- TMEM134 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 37/115 reads (32%) | called by muse, mutect2, varscan2
- TOB2 | c.839G>C p.S280T | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); called by mutect2, varscan2
- TSPYL2 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- WDR87 | c.6360C>G p.I2120M | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ZNF100 | c.1007G>C p.R336T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.21); called by mutect2, varscan2
- ZNF197 | c.644_649del p.X215_splice | Splice Site (DEL) | VAF 16/33 reads (48%) | called by mutect2, pindel, varscan2
- ZNF496 | c.1605C>A p.D535E | Missense Mutation (SNP) | VAF 108/395 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ACP6 | c.51G>A p.L17= | Silent (SNP) | VAF 79/503 reads (16%) | called by muse, mutect2, varscan2
- AHI1 | c.630G>A p.K210= | Silent (SNP) | VAF 24/44 reads (55%) | called by muse, varscan2
- C17orf64 | c.240C>T p.Y80= | Silent (SNP) | VAF 35/175 reads (20%) | catalogued as COSV52257181; called by muse, mutect2, varscan2
- C5 | c.4482A>G p.T1494= | Silent (SNP) | VAF 30/364 reads (8%) | called by muse, mutect2
- EXOC3L1 | c.717G>A p.Q239= | Silent (SNP) | VAF 73/129 reads (57%) | catalogued as rs1170964101, COSV52047322; called by muse, mutect2, varscan2
- FBLN5 | c.978G>A p.R326= | Silent (SNP) | VAF 97/327 reads (30%) | catalogued as rs775694073; called by muse, mutect2, varscan2
- GPR158 | c.1374C>A p.I458= | Silent (SNP) | VAF 51/157 reads (32%) | called by muse, mutect2, varscan2
- GRK6 | c.141C>G p.L47= | Silent (SNP) | VAF 51/145 reads (35%) | catalogued as COSV100586871; called by muse, mutect2, varscan2
- LMF2 | c.1020C>T p.D340= | Silent (SNP) | VAF 46/296 reads (16%) | catalogued as rs780139990; called by mutect2, varscan2
- LRCH2 | c.1455G>A p.Q485= | Silent (SNP) | VAF 65/110 reads (59%) | called by muse, mutect2, varscan2
- NR5A1 | c.144G>A p.T48= | Silent (SNP) | VAF 164/477 reads (34%) | catalogued as rs201827533; called by muse, mutect2, varscan2
- RALGAPA2 | c.2748C>G p.A916= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as rs539866650, COSV52495885; called by muse, mutect2, varscan2
- SH2D3C | c.1993C>T p.L665= (on ENST00000314830 / NM_170600.3; = p.L508= on NM_005489.4) | Silent (SNP) | VAF 41/135 reads (30%) | called by muse, mutect2, varscan2
- SLC16A9 | c.1074G>A p.L358= | Silent (SNP) | VAF 141/343 reads (41%) | catalogued as rs1456973142; called by muse, mutect2, varscan2
- SLC30A8 | c.822C>T p.L274= | Silent (SNP) | VAF 27/115 reads (23%) | called by muse, mutect2, varscan2
- SLIT1 | c.1162C>T p.L388= | Silent (SNP) | VAF 58/165 reads (35%) | catalogued as COSV56602777; called by muse, mutect2, varscan2
- TMEM168 | c.1197C>G p.L399= | Silent (SNP) | VAF 45/166 reads (27%) | catalogued as rs531214757; called by muse, mutect2, varscan2
- TPO | c.1479C>A p.G493= | Silent (SNP) | VAF 370/510 reads (73%) | called by mutect2, varscan2
- ZNF536 | c.591C>T p.R197= | Silent (SNP) | VAF 87/231 reads (38%) | catalogued as rs375960895; called by muse, mutect2, varscan2
- ZNF91 | c.3336C>T p.G1112= | Silent (SNP) | VAF 47/154 reads (31%) | catalogued as COSV100322532; called by muse, mutect2, varscan2
- ACBD5 | chr10:27196142 G>T | 3'Flank (SNP) | VAF 53/145 reads (37%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27240656 G>A | 5'Flank (SNP) | VAF 91/256 reads (36%) | called by muse, mutect2, varscan2
- BICC1 | c.2533+75G>A | Intron (SNP) | VAF 53/279 reads (19%) | called by muse, mutect2, varscan2
- ESRP1 | chr8:94639272 G>C | 5'Flank (SNP) | VAF 42/113 reads (37%) | called by muse, mutect2, varscan2
- IL1RAP | chr3:190655972 A>T | 3'Flank (SNP) | VAF 361/729 reads (50%) | called by muse, mutect2, varscan2
- IL36B | c.261+927A>T | Intron (SNP) | VAF 158/395 reads (40%) | called by muse, mutect2, varscan2
- L3MBTL2 | c.25-1301_25-1296del | Intron (DEL) | VAF 4/43 reads (9%) | called by pindel, varscan2
- LENG8 | c.*1189G>T | 3'UTR (SNP) | VAF 51/134 reads (38%) | called by muse, mutect2, varscan2
- MDGA2 | c.2752+1499C>T | Intron (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- NCF1C | n.1135C>G | RNA (SNP) | VAF 93/272 reads (34%) | catalogued as rs1554455603; called by muse, mutect2, varscan2
- PDHA1 | c.*2G>T | 3'UTR (SNP) | VAF 100/366 reads (27%) | called by mutect2, varscan2
